Somatic mutation profile of tumor specimen 0DQS00 from CCDI case PBCFGV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.7 years (6,455 days).
Specimen 0DQS00: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8650e2b6-eb63-45e6-a980-c998b80ff6f2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQS0K (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/af70ba62-f056-4d77-ba4a-7e1baec036e1

The open-access MAF lists 37 somatic variants for this specimen: 18 protein-altering or splice-affecting, 9 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 9, 3'UTR 5, Intron 4, In Frame Del 1, Frame Shift Del 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCF1 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 28/596 reads (5%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs767397757, COSV58228252; called by muse, mutect2
- DEFB114 | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 60/1031 reads (6%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.028); catalogued as rs146335986; called by muse, mutect2
- NSD1 | c.5183del p.A1728Vfs*7 | Frame Shift Del (DEL) | VAF 407/1121 reads (36%) | catalogued as COSV61784954; called by mutect2, pindel, varscan2
- UTRN | c.890G>C p.R297P | Missense Mutation (SNP) | VAF 310/689 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.637); catalogued as rs775234532, COSV100839806, COSV100840673; called by muse, mutect2, varscan2
- ZNF462 | c.628G>T p.V210L | Missense Mutation (SNP) | VAF 453/1231 reads (37%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV52932005; called by muse, mutect2, varscan2
- C2orf92 | c.151T>C p.Y51H | Missense Mutation (SNP) | VAF 360/1225 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- DCLK3 | c.1303C>A p.Q435K | Missense Mutation (SNP) | VAF 32/753 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2
- GAL3ST2 | c.404_406del p.F135del | In Frame Del (DEL) | VAF 153/635 reads (24%) | called by mutect2, pindel, varscan2
- HIVEP3 | c.4580G>T p.G1527V | Missense Mutation (SNP) | VAF 424/925 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- LRP1B | c.9499G>T p.V3167F | Missense Mutation (SNP) | VAF 480/1627 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- OTUD4 | c.781T>A p.Y261N (on ENST00000447906 / NM_001366057.1; = p.Y196N on NM_001102653.1) | Missense Mutation (SNP) | VAF 538/1116 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- RTTN | c.2774C>T p.T925I | Missense Mutation (SNP) | VAF 472/975 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- SKOR2 | c.2806A>T p.N936Y | Missense Mutation (SNP) | VAF 288/652 reads (44%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- SLC44A2 | c.487A>T p.I163F | Missense Mutation (SNP) | VAF 209/738 reads (28%) | SIFT tolerated (0.64); PolyPhen benign (0); called by mutect2, varscan2
- SORL1 | c.104T>A p.L35Q | Missense Mutation (SNP) | VAF 36/390 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.193); called by muse, mutect2
- STK31 | c.842+2T>A p.X281_splice | Splice Site (SNP) | VAF 217/452 reads (48%) | called by muse, mutect2, varscan2
- TAF1L | c.503A>G p.D168G | Missense Mutation (SNP) | VAF 473/1052 reads (45%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIM42 | c.681G>T p.W227C | Missense Mutation (SNP) | VAF 352/787 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ABCA13 | c.13278C>T p.D4426= | Silent (SNP) | VAF 445/1017 reads (44%) | catalogued as rs759851947; called by muse, mutect2, varscan2
- DSC3 | c.2124A>T p.L708= | Silent (SNP) | VAF 227/771 reads (29%) | called by muse, mutect2, varscan2
- FAM133B | c.264C>A p.S88= | Silent (SNP) | VAF 498/1087 reads (46%) | called by muse, mutect2, varscan2
- LRRC37A3 | c.798A>G p.P266= | Silent (SNP) | VAF 234/4092 reads (6%) | called by muse, varscan2
- MYO7A | c.1659T>C p.H553= | Silent (SNP) | VAF 394/830 reads (47%) | called by muse, mutect2, varscan2
- PHKA1 | c.1131T>A p.P377= | Silent (SNP) | VAF 242/556 reads (44%) | called by muse, mutect2, varscan2
- PROCR | c.258G>A p.L86= | Silent (SNP) | VAF 187/628 reads (30%) | called by muse, mutect2, varscan2
- RECQL5 | c.789T>A p.I263= | Silent (SNP) | VAF 206/983 reads (21%) | called by muse, mutect2, varscan2
- SESTD1 | c.1674G>A p.L558= | Silent (SNP) | VAF 263/1235 reads (21%) | catalogued as COSV58932719; called by muse, mutect2, varscan2
- ATP6V1A | c.*81A>T | 3'UTR (SNP) | VAF 225/496 reads (45%) | called by muse, mutect2, varscan2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 33/818 reads (4%) | called by muse, mutect2
- ELMO2 | c.1885-52G>A | Intron (SNP) | VAF 284/564 reads (50%) | called by muse, mutect2, varscan2
- ERCC3 | c.*84C>G | 3'UTR (SNP) | VAF 210/726 reads (29%) | called by muse, mutect2, varscan2
- HSPB2 | c.-48C>T | 5'UTR (SNP) | VAF 47/111 reads (42%) | catalogued as rs782753318; called by muse, mutect2, varscan2
- LRRC63 | c.*36T>A | 3'UTR (SNP) | VAF 5/26 reads (19%) | called by mutect2, varscan2
- MAN2C1 | c.2547+20G>A | Intron (SNP) | VAF 278/1022 reads (27%) | called by muse, mutect2, varscan2
- PDCL | c.*5A>C | 3'UTR (SNP) | VAF 268/563 reads (48%) | called by muse, mutect2, varscan2
- PRAG1 | c.*47T>C | 3'UTR (SNP) | VAF 154/468 reads (33%) | called by muse, mutect2, varscan2
- SIGLEC10 | c.755-26_755-23del | Intron (DEL) | VAF 141/388 reads (36%) | catalogued as rs780236342; called by mutect2, pindel, varscan2
